Somatic mutation profile of tumor specimen C3N-03785-03 (aliquot CPT0245680006) from CPTAC case C3N-03785, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.3 years (24,203 days).
Specimen C3N-03785-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2965045-7f89-4e1a-92ec-8ef9800d0e3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03785-31 (Blood Derived Normal), aliquot CPT0245720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67367c4-8f6b-4fc3-b921-b2554b65a636

The open-access MAF lists 165 somatic variants for this specimen: 114 protein-altering or splice-affecting, 31 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 31, Intron 9, Frame Shift Del 6, Nonsense Mutation 4, 5'UTR 3, 5'Flank 3, In Frame Del 2, 3'Flank 2, Frame Shift Ins 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.2828C>A p.S943Y | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs996631522; called by muse, mutect2, varscan2
- ARHGEF16 | c.1195C>G p.R399G | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs761184077, COSV65681674; called by muse, mutect2, varscan2
- C11orf58 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.753); catalogued as COSV57178314; called by muse, mutect2, varscan2
- CDC73 | c.1572G>C p.K524N | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66469288; called by muse, mutect2
- CRACDL | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as rs1449681363; called by muse, mutect2, varscan2
- CTCF | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1259610303, COSV50506072; called by muse, mutect2, varscan2
- CYBRD1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as rs756425559; called by muse, mutect2, varscan2
- DHX33 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.028); catalogued as COSV99342351; called by muse, mutect2, varscan2
- DMC1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282071888, COSV99319313; called by muse, mutect2, varscan2
- FAT4 | c.14063C>A p.S4688Y | Missense Mutation (SNP) | VAF 117/185 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV58690701; called by muse, mutect2, varscan2
- FOXG1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1422876736; called by muse, mutect2, varscan2
- GAGE1 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs373578063, COSV67747571; called by muse, mutect2, varscan2
- GCN1 | c.7393G>A p.V2465I | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs775818302; called by muse, mutect2, varscan2
- GRIP1 | c.3367G>A p.E1123K (on ENST00000359742 / NM_001379345.1; = p.E1071K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as COSV54014278; called by muse, mutect2, varscan2
- HBS1L | c.704T>G p.V235G | Missense Mutation (SNP) | VAF 187/511 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63202949; called by muse, mutect2, varscan2
- HEATR5B | c.3740C>T p.T1247I | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51853086; called by muse, mutect2, varscan2
- IGLV1-44 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 136/361 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs1431215187; called by muse, mutect2, varscan2
- KCNK2 | c.847G>A p.D283N (on ENST00000444842 / NM_001017425.3; = p.D268N on NM_014217.4) | Missense Mutation (SNP) | VAF 154/254 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs374646942; called by muse, mutect2, varscan2
- LHX6 | c.1061G>T p.R354L (on ENST00000373755 / NM_001242334.2; = p.R383L on NM_014368.5) | Missense Mutation (SNP) | VAF 158/252 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs774135453, COSV100493498, COSV61344311; called by muse, mutect2, varscan2
- LINGO1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs764093658, COSV62436378; called by muse, mutect2, varscan2
- LRP5 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 190/2497 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53712407; called by muse, mutect2
- MARVELD3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs780239821; called by muse, mutect2, varscan2
- MORC1 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV51713766, COSV51717234; called by muse, mutect2, varscan2
- PCDH17 | c.1541C>G p.S514W | Missense Mutation (SNP) | VAF 144/207 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64971600; called by muse, mutect2, varscan2
- PIEZO1 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs747323210, COSV56339356; called by muse, mutect2, varscan2
- PTOV1 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV55587182; called by muse, mutect2, varscan2
- PUM2 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as rs768358866; called by muse, mutect2, varscan2
- RBMXL3 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100407264; called by muse, mutect2, varscan2
- RNF151 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 121/176 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs749239059; called by muse, mutect2, varscan2
- RP1L1 | c.6500A>T p.Q2167L | Missense Mutation (SNP) | VAF 285/986 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66754331; called by muse, mutect2
- SALL1 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs528231499, COSV51754765; called by muse, mutect2, varscan2
- SPTBN1 | c.2737C>G p.R913G | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV61690516; called by muse, mutect2, varscan2
- TOMM70 | c.1578T>A p.D526E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs1397987428; called by muse, mutect2, varscan2
- TRIO | c.5749G>A p.V1917M | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1174403108; called by muse, mutect2, varscan2
- TSHZ1 | c.1412C>T p.P471L (on ENST00000580243 / NM_001308210.2; = p.P426L on NM_005786.6) | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs142270240; called by muse, mutect2, varscan2
- USP12 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs771651005; called by muse, mutect2, varscan2
- VSTM4 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039609, COSV53677023; called by muse, mutect2, varscan2
- ZFP64 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1402140728; called by muse, mutect2, varscan2
- ZIC1 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1486555123; called by muse, mutect2, varscan2
- ZNF33A | c.1580A>T p.Y527F (on ENST00000458705 / NM_006974.3; = p.Y528F on NM_006954.2) | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.867); catalogued as rs1323833535; called by muse, mutect2, varscan2
- ZNF79 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 137/179 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs764374022; called by muse, mutect2, varscan2
- AC004593.2 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 222/574 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ADAM32 | c.1547C>A p.A516D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ANKRD17 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- APC | c.3381_3404delinsTT p.Q1127Hfs*31 | Frame Shift Del (DEL) | VAF 41/81 reads (51%) | called by pindel, varscan2*
- APC | c.5222T>G p.F1741C | Missense Mutation (SNP) | VAF 180/268 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ARHGAP12 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 87/249 reads (35%) | called by muse, mutect2, varscan2
- ASTN1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 264/518 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP5F1A | c.140-3dup | Splice Region (INS) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.4549A>C p.T1517P | Missense Mutation (SNP) | VAF 117/157 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by mutect2, varscan2
- C11orf95 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- C2orf69 | c.954_957del p.K318Nfs*13 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- CACNA1A | c.3748G>C p.E1250Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- CAPRIN2 | c.1582T>G p.S528A | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC33 | c.1520A>G p.Q507R | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CD74 | c.65A>T p.D22V | Missense Mutation (SNP) | VAF 260/315 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DBX1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 206/600 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMD | c.5705G>C p.S1902T | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.51); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DNAH3 | c.7760G>A p.C2587Y | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNA1 | c.247_252del p.Q83_S84del | In Frame Del (DEL) | VAF 469/931 reads (50%) | called by mutect2, pindel, varscan2
- EXOSC4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 157/421 reads (37%) | called by muse, mutect2, varscan2
- FAM169A | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- FAM83B | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCER2 | c.965G>C p.*322Sext*29 | Nonstop Mutation (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- FER1L5 | c.2819C>A p.A940E (on ENST00000623019; = p.A947E on NM_001293083.2) | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- FUT4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 228/604 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GADD45B | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- GADD45GIP1 | c.388_389del p.Q130Dfs*19 | Frame Shift Del (DEL) | VAF 66/206 reads (32%) | called by pindel, varscan2
- GLRB | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HECTD4 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HEMGN | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 110/164 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- HERC2 | c.8722A>T p.I2908F | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- HERC2 | c.7120C>G p.P2374A | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- HPR | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 120/315 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HTR2C | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.309); called by muse, varscan2
- IGHMBP2 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 50/1308 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.201); called by muse, mutect2
- IGSF22 | c.1697C>A p.A566E | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGB6 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNJ12 | c.1196G>C p.R399P | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCTD15 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 71/93 reads (76%) | called by muse, mutect2, varscan2
- KIF22 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- LCOR | c.3989A>T p.E1330V | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCTL | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MALT1 | c.1767T>G p.S589R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MECP2 | c.280A>C p.M94L | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MRPS5 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MUC17 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPFFR1 | c.812dup p.M271Ifs*116 | Frame Shift Ins (INS) | VAF 137/415 reads (33%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1047A>G p.I349M | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PITX3 | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLCB1 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PPP4R3C | c.945A>C p.E315D | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.35); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RCOR2 | c.452del p.G151Afs*15 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- RHOV | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPF2 | c.678G>T p.R226S | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SAMD4A | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 299/519 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SBSN | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 194/444 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, varscan2
- SHISA4 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SNIP1 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 110/468 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SUPT16H | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TCN1 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TECPR1 | c.2609G>A p.W870* | Nonsense Mutation (SNP) | VAF 91/160 reads (57%) | called by muse, mutect2, varscan2
- TG | c.6535G>C p.E2179Q | Missense Mutation (SNP) | VAF 139/356 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- THOC3 | c.350del p.T117Rfs*13 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, varscan2
- TIMM13 | c.172_183del p.L58_S61del | In Frame Del (DEL) | VAF 68/185 reads (37%) | called by mutect2, pindel, varscan2
- TMEM221 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TNXB | c.2744C>A p.A915E | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TP53 | c.911_914del p.T304Sfs*40 | Frame Shift Del (DEL) | VAF 374/502 reads (75%) | called by mutect2, pindel, varscan2
- TRANK1 | c.3718A>G p.T1240A | Missense Mutation (SNP) | VAF 183/219 reads (84%) | SIFT tolerated (0.68); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTC19 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 97/136 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TTN | c.72886G>T p.V24296L (on ENST00000591111; = p.V16872L on NM_003319.4) | Missense Mutation (SNP) | VAF 100/251 reads (40%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- USP32 | c.4683dup p.L1562Sfs*4 | Frame Shift Ins (INS) | VAF 72/136 reads (53%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF791 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEST1 | c.864G>A p.L288= | Silent (SNP) | VAF 202/520 reads (39%) | called by muse, mutect2, varscan2
- CACNA1A | c.3828G>A p.R1276= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1435600305; called by muse, varscan2
- CHEK1 | c.1011A>G p.K337= | Silent (SNP) | VAF 199/245 reads (81%) | catalogued as rs779758431; called by muse, mutect2, varscan2
- COPG1 | c.483G>T p.V161= | Silent (SNP) | VAF 152/188 reads (81%) | called by muse, mutect2, varscan2
- CRISP1 | c.120A>G p.V40= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs1156943563; called by muse, mutect2, varscan2
- DMBT1 | c.6861A>T p.G2287= (on ENST00000338354 / NM_001377530.1; = p.G1530= on NM_004406.3) | Silent (SNP) | VAF 99/257 reads (39%) | called by muse, mutect2, varscan2
- DNAH10 | c.2502C>T p.V834= (on ENST00000409039; = p.V773= on NM_207437.3) | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- DSEL | c.246C>T p.I82= | Silent (SNP) | VAF 51/145 reads (35%) | called by muse, mutect2, varscan2
- FAM131B | c.432T>C p.S144= | Silent (SNP) | VAF 136/179 reads (76%) | catalogued as rs535505437; called by muse, mutect2, varscan2
- FAM160B1 | c.403T>C p.L135= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1223971022; called by muse, mutect2, varscan2
- GC | c.213C>A p.T71= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs750307767; called by muse, mutect2, varscan2
- GCA | c.534T>C p.Y178= | Silent (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- GDF10 | c.786G>A p.T262= | Silent (SNP) | VAF 155/383 reads (40%) | catalogued as rs1555207567; called by muse, mutect2, varscan2
- GOLGA8A | c.91C>T p.L31= | Silent (SNP) | VAF 192/1018 reads (19%) | called by mutect2, varscan2
- GPR153 | c.1440C>T p.P480= | Silent (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- H2AC12 | c.45C>T p.A15= | Silent (SNP) | VAF 87/185 reads (47%) | catalogued as rs369580045; called by muse, mutect2, varscan2
- KMT5C | c.1287G>A p.P429= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs184329439; called by muse, mutect2, varscan2
- LRRC9 | c.3816T>C p.S1272= | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- MAN2B1 | c.939G>A p.V313= | Silent (SNP) | VAF 161/372 reads (43%) | called by muse, mutect2, varscan2
- MDN1 | c.6261A>G p.L2087= | Silent (SNP) | VAF 192/432 reads (44%) | catalogued as COSV65524293; called by muse, mutect2, varscan2
- MMP25 | c.1329G>A p.A443= | Silent (SNP) | VAF 131/178 reads (74%) | called by muse, mutect2, varscan2
- MRPS26 | c.22C>T p.L8= | Silent (SNP) | VAF 92/234 reads (39%) | called by muse, mutect2, varscan2
- MUC16 | c.1044C>G p.S348= | Silent (SNP) | VAF 125/329 reads (38%) | called by muse, mutect2, varscan2
- MYO18B | c.2949C>T p.T983= | Silent (SNP) | VAF 115/243 reads (47%) | catalogued as COSV59149017; called by muse, mutect2, varscan2
- PCDHB15 | c.1596C>T p.G532= | Silent (SNP) | VAF 83/450 reads (18%) | called by muse, mutect2, varscan2
- PRKAA1 | c.246C>T p.F82= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs775222791, COSV57182977, COSV99713460; called by muse, mutect2, varscan2
- PXDN | c.1467C>T p.I489= | Silent (SNP) | VAF 91/277 reads (33%) | called by muse, mutect2, varscan2
- SCN1A | c.720G>T p.L240= | Silent (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- SV2B | c.1101C>T p.F367= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV57702723; called by muse, mutect2, varscan2
- TMPRSS9 | c.2754C>T p.G918= (on ENST00000648592; = p.G884= on NM_182973.2) | Silent (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
- YTHDC1 | c.2181A>G p.R727= (on ENST00000344157 / NM_001031732.4; = p.R709= on NM_133370.4) | Silent (SNP) | VAF 58/130 reads (45%) | called by muse, varscan2
- AC055876.1 | n.371G>A | RNA (SNP) | VAF 53/88 reads (60%) | called by muse, mutect2, varscan2
- ACY1 | c.436+13C>T | Intron (SNP) | VAF 205/259 reads (79%) | called by muse, varscan2
- AP000769.3 | chr11:65503266 A>G | 5'Flank (SNP) | VAF 43/93 reads (46%) | catalogued as rs757314892; called by muse, mutect2, varscan2
- AVIL | c.1195-142T>A | Intron (SNP) | VAF 103/289 reads (36%) | called by muse, mutect2, varscan2
- CDT1 | c.-8C>T | 5'UTR (SNP) | VAF 147/353 reads (42%) | catalogued as rs760203813; called by muse, mutect2, varscan2
- COL5A1 | c.654+7455T>A | Intron (SNP) | VAF 152/216 reads (70%) | called by muse, mutect2, varscan2
- EFEMP2 | chr11:65872811 C>T | 5'Flank (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- KIAA1109 | c.2793+66G>A | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- NEB | c.2310+32A>T | Intron (SNP) | VAF 70/169 reads (41%) | called by muse, mutect2, varscan2
- NOP14 | c.-7G>A | 5'UTR (SNP) | VAF 64/153 reads (42%) | catalogued as rs763379198; called by muse, mutect2, varscan2
- PRDM15 | c.-397G>A | 5'UTR (SNP) | VAF 30/47 reads (64%) | catalogued as rs376979380; called by muse, mutect2, varscan2
- RCC1 | c.-261-629G>C | Intron (SNP) | VAF 106/368 reads (29%) | called by muse, mutect2, varscan2
- RERE | c.830+15444C>T | Intron (SNP) | VAF 51/97 reads (53%) | catalogued as COSV61947394, COSV61947486; called by muse, mutect2, varscan2
- SBF2 | c.3455+23A>G | Intron (SNP) | VAF 117/298 reads (39%) | called by muse, mutect2, varscan2
- SCML2P1 | chr18:6928467 C>A | 3'Flank (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3194C>A | RNA (SNP) | VAF 133/381 reads (35%) | called by muse, mutect2, varscan2
- SYT14 | c.*828C>G | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- TNRC18 | chr7:5427942 C>A | 5'Flank (SNP) | VAF 198/501 reads (40%) | catalogued as rs1391488517; called by muse, mutect2, varscan2
- USP34 | chr2:61186694 A>T | 3'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- WT1 | c.1063-12C>G | Intron (SNP) | VAF 151/409 reads (37%) | called by muse, mutect2, varscan2
